Somatic mutation profile of tumor specimen ALCH-B1P4-TTP1-A (aliquot ALCH-B1P4-TTP1-A-1-0-D-A76Z-36) from ALCHEMIST case ALCH-B1P4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.6 years (24,309 days).
Specimen ALCH-B1P4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 663afa03-05fe-452b-8884-671d6cf05ef2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1P4-NB1-A (Blood Derived Normal), aliquot ALCH-B1P4-NB1-A-1-0-D-A76Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/285b0a59-0faa-4916-a834-f8d38cf0581b

The open-access MAF lists 125 somatic variants for this specimen: 91 protein-altering or splice-affecting, 19 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 19, Intron 6, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 3, RNA 2, 3'UTR 2, 5'Flank 2, 3'Flank 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121917927, CM031346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-2A>T p.X126_splice | Splice Site (SNP) | VAF 28/82 reads (34%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRF3 | c.2026G>A p.D676N (on ENST00000311519 / NM_001145168.1; = p.D477N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs763331125; called by muse, mutect2, varscan2
- AGRN | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs139590454; called by muse, mutect2, varscan2
- AK7 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50870734; called by muse, mutect2, varscan2
- APLNR | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758486436, COSV57242880; called by muse, mutect2
- ATXN7L3 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV66989341, COSV66989680; called by muse, mutect2
- BCL9 | c.1971G>C p.E657D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782363194; called by muse, mutect2, varscan2
- CABS1 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99078821, COSV99909149; called by muse, mutect2, varscan2
- CASZ1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as rs372540625; called by muse, mutect2
- CCDC22 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.084); catalogued as COSV100873075; called by muse, mutect2, varscan2
- CCDC88C | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV66241015; called by muse, mutect2
- CD33 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as rs754116392; called by muse, mutect2, varscan2
- CNGB1 | c.3148G>C p.G1050R | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs578138182, COSV51897193; called by muse, mutect2, varscan2
- CST5 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.072); catalogued as rs761896231; called by muse, mutect2, varscan2
- DCHS1 | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs771473186; called by muse, mutect2, varscan2
- FER1L6 | c.2684C>G p.P895R | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67550868; called by muse, mutect2, varscan2
- ILVBL | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs536567026; called by muse, mutect2, varscan2
- NEUROD2 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs759074299; called by muse, varscan2
- NOVA1 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.584); catalogued as COSV57479302; called by muse, mutect2, varscan2
- PRDM5 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as rs759022476, COSV53367325; called by muse, mutect2
- PSKH2 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs752800945; called by muse, mutect2, varscan2
- RANBP1 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV59334145; called by muse, mutect2, varscan2
- RB1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 65/214 reads (30%) | catalogued as CM942037, COSV57311318; called by muse, mutect2, varscan2
- RSPO4 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV54083772; called by muse, mutect2, varscan2
- SHANK2 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV53588565; called by muse, mutect2, varscan2
- SPATA1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/252 reads (11%) | catalogued as rs1280624339; called by muse, mutect2, varscan2
- TMPRSS11A | c.165T>G p.F55L | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV100602616; called by muse, mutect2, varscan2
- TP53 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs1567558112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13D | c.5146G>A p.V1716M | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99165309; called by muse, mutect2, varscan2
- VRK1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53711110; called by muse, mutect2
- XIRP2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV54727191; called by muse, mutect2, varscan2
- ZNF385B | c.1055G>C p.G352A | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1218130500; called by muse, mutect2, varscan2
- ACSL6 | c.899T>C p.F300S (on ENST00000379240; = p.F325S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2
- ADAM7 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- AJM1 | c.2779_2787del p.F927_E929del | In Frame Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- ALDH2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ALKBH1 | c.528T>G p.H176Q | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ANGPT1 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP13A3 | c.2479C>A p.H827N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- BTBD8 | c.2039G>C p.G680A (on ENST00000636805 / NM_001376131.1; = p.G167A on NM_015237.4) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CALCRL | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2
- CDCA7 | c.320A>G p.E107G (on ENST00000347703 / NM_145810.3; = p.E186G on NM_031942.5) | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CDCP1 | c.2327del p.P776Hfs*41 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- CDH9 | c.770C>G p.T257R | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CHST11 | c.565T>C p.F189L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CPNE8 | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CRTC1 | c.732dup p.S245Vfs*206 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- CYP3A43 | c.1027G>C p.A343P | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, varscan2
- DRP2 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ELFN2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- FARSB | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- FOLR1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN3 | c.393T>A p.N131K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IGHMBP2 | c.1683C>G p.I561M | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- IL16 | c.2278A>T p.K760* (on ENST00000302987 / NM_172217.5; = p.K59* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ITGA11 | c.3317A>T p.N1106I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIF20A | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2E | c.4876G>A p.V1626I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2
- LORICRIN | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | PolyPhen benign (0.367); called by muse, mutect2, varscan2
- LRP1B | c.11101G>T p.D3701Y | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP2 | c.4260G>C p.M1420I | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- LRRC38 | c.336C>A p.S112R | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MAGEB5 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- MGME1 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1F | c.771+6C>A | Splice Region (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- NEK10 | c.2346G>T p.M782I | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NF1 | c.6969_6974del p.Q2324_L2325del (on ENST00000358273 / NM_001042492.3; = p.Q2303_L2304del on NM_000267.3) | In Frame Del (DEL) | VAF 43/215 reads (20%) | called by mutect2, pindel, varscan2
- NRXN3 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4D10 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR4S1 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PABPC3 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- PIK3R4 | c.4048A>G p.R1350G | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PKD1L3 | c.1562A>G p.H521R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PPP4R3A | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- PTEN | c.133_138del p.V45_Y46del | In Frame Del (DEL) | VAF 41/228 reads (18%) | called by mutect2, pindel, varscan2
- RDX | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RELB | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCN5A | c.2921A>G p.K974R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SGK2 | c.226del p.A76Pfs*48 | Frame Shift Del (DEL) | VAF 53/156 reads (34%) | called by mutect2, pindel, varscan2
- SLC38A4 | c.796A>C p.T266P | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2
- SLC6A19 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SPATS2L | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TAF1L | c.2402T>A p.V801D | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TNNI3 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPBG | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRIM55 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM64C | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TTN | c.35444del p.P11815Hfs*6 (on ENST00000591111; = p.P10888Hfs*6 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/155 reads (17%) | called by mutect2, pindel, varscan2
- XPNPEP2 | c.1_31del p.M1_?11 | Translation Start Site (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- ZFPM2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ABCA3 | c.399G>A p.V133= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- AGR2 | c.108T>A p.S36= | Silent (SNP) | VAF 69/252 reads (27%) | called by muse, mutect2, varscan2
- HECW1 | c.402T>C p.N134= | Silent (SNP) | VAF 53/283 reads (19%) | called by muse, mutect2, varscan2
- MYH6 | c.1950G>C p.S650= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV62449955; called by muse, mutect2, varscan2
- OR10G7 | c.285C>T p.S95= | Silent (SNP) | VAF 27/280 reads (10%) | catalogued as COSV100389935; called by muse, mutect2
- PARP14 | c.828C>T p.D276= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs755153910; called by muse, mutect2, varscan2
- PCDHGA9 | c.1494G>T p.G498= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- POLR1G | c.1413G>C p.R471= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- SBF2 | c.1648C>T p.L550= | Silent (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- SHB | c.507G>T p.R169= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- SIRPB1 | c.696C>A p.I232= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- SLC25A41 | c.237C>A p.V79= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1423048282; called by muse, mutect2, varscan2
- STXBP4 | c.1260A>G p.R420= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as rs1443501208; called by muse, mutect2, varscan2
- TGM6 | c.1371G>T p.A457= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99172933; called by muse, mutect2, varscan2
- UPK1A | c.570C>T p.C190= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- ZNF155 | c.1083G>A p.K361= | Silent (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- ZNF320 | c.372C>T p.D124= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV101206887; called by muse, mutect2, varscan2
- ZNF479 | c.519T>C p.N173= | Silent (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- ZNF492 | c.1206T>C p.F402= | Silent (SNP) | VAF 21/340 reads (6%) | catalogued as rs1245838680, COSV71762319; called by muse, mutect2
- DST | c.414+7035dup | Intron (INS) | VAF 71/453 reads (16%) | called by mutect2, pindel, varscan2
- ELN | c.196+35C>T | Intron (SNP) | VAF 45/124 reads (36%) | catalogued as rs781847678; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888353 C>A | 3'Flank (SNP) | VAF 26/378 reads (7%) | catalogued as COSV58046107; called by muse, mutect2
- FAM183BP | n.996C>A | RNA (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+1087C>T | Intron (SNP) | VAF 27/173 reads (16%) | catalogued as rs1555871078; called by muse, mutect2, varscan2
- HSPA7 | n.570G>T | RNA (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- IRAG2 | c.3001+17A>G | Intron (SNP) | VAF 27/110 reads (25%) | catalogued as rs770088025; called by muse, varscan2
- LHX6 | chr9:122228297 C>T | 5'Flank (SNP) | VAF 30/87 reads (34%) | catalogued as rs1039015000; called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16371456 G>T | 3'Flank (SNP) | VAF 20/67 reads (30%) | called by mutect2, varscan2
- RBBP7 | c.-41G>T | 5'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- SULF1 | c.*487T>G | 3'UTR (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- TMEM245 | c.*48C>T | 3'UTR (SNP) | VAF 59/180 reads (33%) | catalogued as rs779404324; called by muse, mutect2, varscan2
- TRIM7 | c.619-15C>G | Intron (SNP) | VAF 16/76 reads (21%) | called by muse, varscan2
- WT1 | chr11:32439691 A>T | 5'Flank (SNP) | VAF 8/45 reads (18%) | catalogued as rs1263306740; called by muse, mutect2, varscan2
- ZBBX | c.2138-9558C>T | Intron (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
